FM case AD15993 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/1622a6b8-c9bf-4505-ac40-f5f1fb1acb1a

Female, 44.4 years: Adrenal cortical carcinoma (ICD-O-3 8370/3) of the adrenal gland; metastasis biopsied or resected from the adrenal gland. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
